Surgical pathology report (de-identified scan), TCGA case TCGA-ZJ-AAXJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site NCI HRE Branch, specimen TCGA-ZJ-AAXJ-01A (Primary Tumor).

SPEC #: _____ Status: _____ Obtained: _____ Received: _____

CLINICAL HISTORY:
233.1

SPECIMEN/PROCEDURE:
1. CERVIX

IMPRESSION:

CERVICAL BIOPSY:

Invasive squamous cell carcinoma, large cell keratinizing.

Dictated by:
Entered:

GROSS DESCRIPTION:

This case is part of the

Received in formalin labeled "cervical biopsy" and with patient name, is one irregular pink-tan to gray-tan glistening portion of tissue, 0.7 x 0.6 x 0.4 cm. The specimen is trisected and entirely submitted in one cassette.

Dictated by:
Entered:

CPT Codes:
CERVICAL BIOPSY/88305

ICD9 Codes:
180.9

Electronically Signed by: _____

*ICD9.3
Carcinoma, squamous cell keratinizing NOS
Site: Cervix NOS C53.9
7/26/14*

** END OF REPORT **

Source: NCI Genomic Data Commons file c7557d84-8232-44ac-9c4f-a8f05f4e9d2f (TCGA-ZJ-AAXJ.0C3B91DD-9AA5-4D08-8B07-2E6DFA0E51A3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).